Surgical pathology report (de-identified scan), TCGA case TCGA-34-5240, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5240-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The left upper lobectomy demonstrates a moderately differentiated squamous cell carcinoma, diameter 5.0 cm. unassociated with visceral pleural or angiolymphatic invasion with one of fifteen N1 lymph nodes positive for metastases but no evidence of metastases in the N2 lymph nodes. Pathologic stage T2N1MX.

- PART 1: LYMPH NODES, SUBINOMINATE LYMPH NODE, BIOPSY –
SIX FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 2: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY –
TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 3: LYMPH NODE, RIGHT TRACHEAL BRONCHIAL LYMPH NODE, BIOPSY –
TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 4: LYMPH NODE, RIGHT PARATRACHEAL LYMPH NODE, BIOPSY –
THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE AND NO EVIDENCE OF MALIGNANCY.
- PART 5: LYMPH NODE, LEFT TRACHEAL BRONCHIAL LYMPH NODE, BIOPSY –
THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE AND AN OLD FIBROCALCIFIC NODULE. NO EVIDENCE OF MALIGNANCY.
- PART 6: LYMPH NODE, INFERIOR PULMONARY LIGAMENT LEFT LYMPH NODE, BIOPSY –
THREE FRAGMENTS OF LYMPH NODE WITH OLD FIBROCALCIFIC GRANULOMA AND REACTIVE CHANGES. NO EVIDENCE OF MALIGNANCY. GROCOTT AND ACID-FAST STAINS FOR MICROORGANISMS ARE NEGATIVE. CORRELATION WITH CULTURE RESULT SUGGESTED.
- PART 7: LYMPH NODE, ANTERIOR HILAR LYMPH NODE, BIOPSY –
TWO LYMPH NODES WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 8: LYMPH NODE, "HILAR LYMPH NODES", BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 9: LUNG, LEFT UPPER LOBE, LOBECTOMY –
A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH BASALOID FEATURES. DIAMETER 5.0 CM. NO EVIDENCE OF VISCERAL PLEURAL OR ANGIOLYMPHATIC INVASION. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T2N1MX.
B. ONE OF ELEVEN N1 LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.
C. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.
D. PULMONARY APICAL CAP.
E. BENIGN CARCINOID TUMORLETS.
- PART 10: LYMPH NODE, AP WINDOW LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 11: LYMPH NODE, PERIAORTIC LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 12: LYMPH NODE, INFERIOR PULMONARY LIGAMENT LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- PART 13: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY –
TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

Source: NCI Genomic Data Commons file a02493ce-a92d-438d-bd0f-e1ef8c0d52b9 (TCGA-34-5240.060BA86B-73EB-4636-B706-D813BEE1DD5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).